Surgical pathology report (de-identified scan), TCGA case TCGA-CD-8528, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site ILSBio, specimen TCGA-CD-8528-01A (Primary Tumor).

[page 1 of 6]
Clinical Information

HISTORY OF PRESENT ILLNESS

Chief Complaints: Abdominal pain, black & tarry stool

Symptoms: weight loss, tired of eating

Clinical Findings:

Performance Scale (Karnofsky Score):

- ☐ 100 Asymptomatic ☐ 80-90 Symptomatic but Fully Ambulatory ☒ 60-70 Symptomatic, in bed less than 50% of day
☐ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden

CURRENT MEDICATIONS

Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)		
				/	/	To / /
				/	/	To / /
				/	/	To / /
				/	/	To / /
				/	/	To / /
				/	/	To / /

[page 2 of 6]
PAST MEDICAL HISTORY

Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status

OB/GYN HISTORY

Menopausal Status	Date of First Menses	
☒ Pre-menopausal	13 years old	
☒ Peri-Menopausal	Date of Last Menses	
☐ Post-menopausal		
Birth Control: ☐ Condom ☐ Oral Contraceptive ☐ IUD ☐ Other: _____		Therapy: _____

SOCIAL HISTORY

Occupation:		Environmental Hazards:		
Smoking History				
Current Status	TYPE	Packs/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Alcohol Consumption				
Current Status	TYPE	Drinks/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Drug Use				
Current Status	TYPE	Frequency	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)

FAMILY MEDICAL HISTORY

Relative	Diagnosis	Age of Diagnosis

LAB DATA

Test	Result	Date	Test	Result	Date
HIV	☒ Negative ☐ Positive: _____		CEA	☐ Negative ☐ Positive: _____	
Hep B	☒ Negative ☐ Positive: _____		CA 15-3	☐ Negative ☐ Positive: _____	
Hep C	☒ Negative ☐ Positive: _____		CA 19-9	☐ Negative ☐ Positive: _____	
AFP	☐ Negative ☐ Positive: _____		PSA	☐ Negative ☐ Positive: _____	
Other:	☐ Negative ☐ Positive: _____		Other:	☐ Negative ☐ Positive: _____	

B/T Cell Markers:

[page 3 of 6]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound		
X-Ray		
CT		
Endoscopy x	A tumour was found in the Stomach	
MRI		
Biopsy	carcinoma	

CLINICAL DIAGNOSIS	
Preoperative Clinical Diagnosis	
Location of Suspected Involved Lymph Nodes	Location of Suspected Distant Metastasis
Clinical Staging	
T4 N0 M0	Stage: IIIA

Treatment Information

SURGICAL TREATMENT			
Procedure		Date of Procedure	
Extended Gastrectomy			
Primary Tumor			
Organ	Detailed Location	Size	
Stomach Tumor	pylorus	5 x 4 x 3 cm	
Extension of Tumor			
Lymph Nodes			
Description	Location of Lymph Nodes	# of Lymph Nodes	
Palpable, Non-Dissected Lymph Nodes			
Dissected Lymph Nodes			
Distant Metastasis			
Organ	Detailed Location	Size	
Surgical Staging			
T4 N0 M0		Stage: IIIA	

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)					
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)	
				/ / To / /	
				/ / To / /	
				/ / To / /	
				/ / To / /	
				/ / To / /	

[page 4 of 6]
Pathology Form

Specimen Information

SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
4	2	4	2			4	2
Time to LN2		Time to Formalin		Time to LN2			
12 min		13 min					

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
Stomach Tumor	5 x 4 x 3 cm	pylorus	6 cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Distant Metastasis			
Organ	Detailed Location	Size	
Pathological Staging			
pT ₄ N ₀ M ₀		Stage: III	
Notes:			

[page 5 of 6]
Microscopic Description

Histological Pattern									
Cell Distribution			+	-	Structural Pattern			+	-
Diffuse			✗		Streaming				
Mosaic					Storiform				
Necrosis					Fibrosis				
Lymphocytic Infiltration			✗		Palisading				
Vascular Invasion					Cystic Degeneration				
Clusterized					Bleeding				
Alveolar Formation					Myxoid Change				
Indian File					Psammoma/Calcification				

Cellular Differentiation											
Squamous	+	-	Adenomatous	+	-	Sarcomatous	+	-	Lymphomatous	+	-
Squamoid Cell			Glandular cell	✗		Round Cell			Large Cell		
Spindle Cell			Cell Stratification			Fibroblast			Small Cell		
Keratin			Secretion			Osteoblast			RS Cell/RS Like		
Desmosome			Intracyt. Vacuole			Lipoblast			Inflam. Cell		
Pearl			Gland formation	✗		Myoblast			Plasma Cell		

Cellular Differentiation: Well Moderate ☒ Poor

Nuclear Appearance				
Nuclear Atypia:	0	I	II	III
Aniso Nucleosis		✗		
Hyperchromatism			✗	
Nucleolar Prominent			✗	
Multinucleated Giant Cell			✗	
Mitotic Activity			✗	

Nuclear Grade:

IHC Data			
Marker	Result	Value	Date
ER	☐ Negative ☐ Positive		
PR	☐ Negative ☐ Positive		
Her-2/neu	☐ Negative ☐ Positive		
B-Cell Marker	☐ Negative ☐ Positive		
T-Cell Marker	☐ Negative ☐ Positive		
Other:	☐ Negative ☐ Positive		
Other:	☐ Negative ☐ Positive		

Final Pathology Report

Histological Diagnosis: Adenocarcinoma of the stomach
(Moderately differentiated) **Grade:** II

Comments:

[page 6 of 6]
CONSOLIDATED DIAGNOSTIC PATHOLOGY FORM*

Microscopic Appearance:

1. Histological pattern:

CELL DISTRIBUTION			STRUCTURAL PATTERN		
	+	-		+	-
Diffuse			Streaming		
Mosaic		X	Storiform		
Necrosis	X		Fibrosis		
Lymphocytic Infiltration	X		Palisading		
Vascular Invasion	X		Cystic Degeneration		
Clusterized	X		Bleeding		
Alveolar Formation	X		Myxoid Change		
Indian File	X		Psammoma/Calcification		

2. Cellular features:

Squamous	+	-	Adenomatous	+	-	Sarcomatous	+	-	Lymphomatous	+	-
Squamoid Cell			Glandular cell	X		Round Cell			Large Cell		
Spindle Cell			Cell Stratification	X		Fibroblast			Small Cell		
Keratin			Secretion	X		Osteoblast			RS Cell/RS Like		
Desmosome			Intracyt. Vacuole	X		Lipoblast			Inflam. Cell		
Pearl			Gland formation	X		Myoblast			Plasma Cell		
Otherwise Specified: D1 70% D2 80% D3 80% D4 80% 170											

2. Cellular Differentiation:

Well	Moderately	Poor
		X

3. Nuclear Atypia:

Nuclear Appearance	0	I	II	III
Aniso Nucleosis				X
Hyperchromatism				X
Nucleolar Prominent				X
Multinucleated Giant Cell				X
Mitotic Activity				X
Nuclear Grade				2

poorly differentiated

Histological Diagnosis: Adeno Carcinoma NOS, G2

Comments:

Source: NCI Genomic Data Commons file 81e33536-9646-4190-bcf6-763ca6cc9a98 (TCGA-CD-8528.AFC740B2-5621-4B8C-B25A-600B4DC2C22E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).